Somatic mutation profile of tumor specimen TCGA-DJ-A3UK-01A (aliquot TCGA-DJ-A3UK-01A-11D-A22D-08) from TCGA case TCGA-DJ-A3UK, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 36.0 years (13,145 days).
Specimen TCGA-DJ-A3UK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fa34f275-449c-4995-b217-8b69b939c2d9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DJ-A3UK-10A (Blood Derived Normal), aliquot TCGA-DJ-A3UK-10A-01D-A22D-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/446cbace-4f29-4c03-b7f1-7967f614c8e0

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 silent.
By variant classification: Silent 2, Missense Mutation 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 49/103 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- FXYD4 | c.39C>G p.G13= | Splice Region (SNP) | VAF 112/313 reads (36%) | catalogued as COSV72052751; called by muse, mutect2, varscan2
- HCAR1 | c.742C>T p.P248S | Missense Mutation (SNP) | VAF 4/94 reads (4%) | SIFT tolerated (0.73); PolyPhen benign (0.01); catalogued as COSV63678004; called by muse, mutect2
- B3GNT6 | c.600G>A p.K200= | Silent (SNP) | VAF 106/220 reads (48%) | catalogued as COSV62829218; called by muse, mutect2
- NAA11 | c.330C>T p.H110= | Silent (SNP) | VAF 19/70 reads (27%) | catalogued as rs774663471, COSV54514307; called by muse, mutect2, varscan2
